Surgical pathology report (de-identified scan), TCGA case TCGA-ZJ-AAXF, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site NCI HRE Branch, specimen TCGA-ZJ-AAXF-01A (Primary Tumor).

SPEC #:

Status:

Obtained:

Received:

CLINICAL HISTORY:

233.1

SPECIMEN/PROCEDURE:

1. CERVIX - BIOPSY

IMPRESSION:

CERVIX, 1 O'CLOCK, BIOPSY:

Invasive squamous cell carcinoma, large cell keratinizing type, moderate to poorly differentiated.

Dictated by:

Entered:

GROSS DESCRIPTION:

This case is part of the

Received in formalin labeled " " and with patient name, is an irregular unoriented tan to red tan glistening portion of tissue, 1.3 x 1 x 0.3 cm. The specimen is trisected. Specimen is entirely submitted in one cassette.

Dictated by:

Entered:

CPT Codes:

CERVICAL BIOPSY/88305

ICD9 Codes:

180.9

Electronically Signed by: _____

ZED-0-3

Carcinoma, squamous cell, large cell
keratinizing NOS 8071/3
Site: Cervix NOS 053.9
7/26/14

** END OF REPORT **

Source: NCI Genomic Data Commons file bfe7f974-6303-4121-adab-9956c210bc57 (TCGA-ZJ-AAXF.DB279590-B849-44D4-B781-BA72CE72C427.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).